Somatic mutation profile of tumor specimen 0DQZ3Q from CCDI case PBCFMX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 5.5 years (2,018 days).
Specimen 0DQZ3Q: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36aa6330-0fb3-49f7-b17d-619f7cfffc5f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQZ3E (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2218eb38-d8ea-4c84-9b2f-40e74f2b5f68

The open-access MAF lists 44 somatic variants for this specimen: 24 protein-altering or splice-affecting, 8 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 8, Intron 7, 3'UTR 2, 5'UTR 1, Frame Shift Del 1, In Frame Del 1, Nonsense Mutation 1, Splice Site 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB1 | c.2962G>A p.V988M | Missense Mutation (SNP) | VAF 160/1264 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.066); catalogued as rs753967146, COSV55965172; called by mutect2, varscan2
- ADGRE1 | c.368G>T p.G123V | Missense Mutation (SNP) | VAF 160/579 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); catalogued as COSV51679096, COSV51679698; called by muse, mutect2, varscan2
- C10orf71 | c.3979G>T p.A1327S | Missense Mutation (SNP) | VAF 55/192 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.171); catalogued as rs1423128225, COSV60515545; called by mutect2, varscan2
- FLNC | c.2476_2478del p.N826del | In Frame Del (DEL) | VAF 114/378 reads (30%) | catalogued as rs1188205440; called by mutect2, pindel, varscan2
- GKAP1 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 288/654 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64488964; called by muse, mutect2, varscan2
- GPR32 | c.68G>T p.R23L | Missense Mutation (SNP) | VAF 45/370 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV54513976; called by muse, mutect2
- MAP7 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 299/726 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.175); catalogued as rs757722809, COSV63422010; called by muse, mutect2, varscan2
- NECAP1 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 100/420 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs766363501; called by muse, mutect2, varscan2
- OR5T2 | c.277C>A p.Q93K | Missense Mutation (SNP) | VAF 59/1957 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV100507136; called by muse, mutect2
- PLA2G4F | c.1823G>A p.R608Q | Missense Mutation (SNP) | VAF 58/430 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs147124089; called by muse, mutect2, varscan2
- PYROXD2 | c.395C>A p.P132H | Missense Mutation (SNP) | VAF 105/653 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as COSV65331569; called by muse, mutect2, varscan2
- SLC11A1 | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 151/534 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs536970437, COSV51915768; called by muse, mutect2, varscan2
- SYCP1 | c.2376del p.D793Tfs*65 | Frame Shift Del (DEL) | VAF 329/1154 reads (29%) | catalogued as rs745637836; called by mutect2, varscan2
- ZNF534 | c.548C>G p.S183C (on ENST00000332323 / NM_001143939.3; = p.S170C on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 190/1143 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.759); catalogued as COSV56514502; called by muse, mutect2, varscan2
- C1orf116 | c.1629G>T p.Q543H | Missense Mutation (SNP) | VAF 38/437 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2
- CAMKK2 | c.597G>T p.K199N | Missense Mutation (SNP) | VAF 111/497 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CUEDC1 | c.169A>T p.M57L | Missense Mutation (SNP) | VAF 200/847 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GDI2 | c.715G>T p.A239S | Missense Mutation (SNP) | VAF 220/1109 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- GFPT1 | c.1468G>A p.V490M (on ENST00000357308 / NM_001244710.2; = p.V472M on NM_002056.4) | Missense Mutation (SNP) | VAF 324/1357 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- KIF26A | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 73/244 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NSD1 | c.3802C>G p.R1268G | Missense Mutation (SNP) | VAF 166/1044 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- PIGB | c.654-1G>C p.X218_splice | Splice Site (SNP) | VAF 141/468 reads (30%) | called by muse, mutect2, varscan2
- PRF1 | c.229G>T p.E77* | Nonsense Mutation (SNP) | VAF 103/551 reads (19%) | called by muse, mutect2, varscan2
- TEX101 | c.706C>A p.L236I (on ENST00000598265 / NM_001130011.3; = p.L254I on NM_031451.4) | Missense Mutation (SNP) | VAF 32/702 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- EIF4G3 | c.4359C>T p.D1453= | Silent (SNP) | VAF 251/842 reads (30%) | catalogued as rs761362334; called by muse, mutect2, varscan2
- IGFBP6 | c.240A>G p.P80= | Silent (SNP) | VAF 36/288 reads (13%) | called by muse, mutect2, varscan2
- JPH1 | c.579C>T p.F193= | Silent (SNP) | VAF 236/790 reads (30%) | catalogued as COSV60611729; called by muse, mutect2, varscan2
- LSR | c.657C>T p.S219= | Silent (SNP) | VAF 44/382 reads (12%) | catalogued as rs371607561; called by muse, mutect2, varscan2
- MMP16 | c.855C>A p.G285= | Silent (SNP) | VAF 236/2218 reads (11%) | catalogued as COSV54161754; called by muse, mutect2, varscan2
- RGSL1 | c.2067T>A p.I689= | Silent (SNP) | VAF 390/1119 reads (35%) | called by muse, mutect2, varscan2
- SPTA1 | c.5301T>A p.P1767= | Silent (SNP) | VAF 26/908 reads (3%) | catalogued as COSV63752475; called by muse, mutect2
- TEKT2 | c.726C>G p.A242= | Silent (SNP) | VAF 77/315 reads (24%) | called by muse, mutect2, varscan2
- BZW2 | c.*5C>G | 3'UTR (SNP) | VAF 52/1234 reads (4%) | called by muse, mutect2
- CAMTA1 | c.-28C>G | 5'UTR (SNP) | VAF 24/84 reads (29%) | called by muse, mutect2, varscan2
- CASTOR1 | c.744-12C>A | Intron (SNP) | VAF 63/203 reads (31%) | called by muse, mutect2, varscan2
- CCHCR1 | c.-51-243C>T | Intron (SNP) | VAF 68/292 reads (23%) | called by muse, mutect2
- CEP112 | c.2394+25529C>A | Intron (SNP) | VAF 34/766 reads (4%) | called by muse, mutect2
- MXRA7 | chr17:76710959 G>C | 5'Flank (SNP) | VAF 19/140 reads (14%) | called by muse, mutect2, varscan2
- NHSL1 | c.203-2996C>T | Intron (SNP) | VAF 32/188 reads (17%) | catalogued as rs192655505; called by muse, mutect2, varscan2
- OR1D4 | n.679C>A | RNA (SNP) | VAF 110/620 reads (18%) | called by mutect2, varscan2
- PRMT5 | c.229+87C>G | Intron (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- RGS14 | c.1254+33_1255-62del | Intron (DEL) | VAF 4/48 reads (8%) | catalogued as rs1207093763; called by mutect2, pindel
- SBNO1 | c.*17A>G | 3'UTR (SNP) | VAF 185/988 reads (19%) | catalogued as rs753791588; called by muse, mutect2, varscan2
- XPNPEP1 | c.1773+14A>T | Intron (SNP) | VAF 29/304 reads (10%) | catalogued as rs377540773; called by muse, mutect2, varscan2
